Somatic mutation profile of tumor specimen BA3405D (aliquot aq-BA3405D) from BEATAML1.0 case 2701, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.1 years (24,522 days).
Specimen BA3405D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22d192ec-80b1-4098-bb6b-1430e6196d49.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3131D (Solid Tissue Normal), aliquot aq-BA3131D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdbc3d49-0ef1-47f6-8e47-0d77ae4f2b9d

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 75/181 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SRSF2 | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 30/68 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs751713049, CM1511359, COSV57969809, COSV57969816, COSV57969830; called by mutect2, varscan2
- LPIN3 | c.1939G>A p.G647S | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111519678, COSV100182732; called by muse, mutect2, varscan2
- RHOJ | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 56/107 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371394112; called by muse, mutect2, varscan2
- VWA8 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.098); catalogued as rs985303286; called by muse, mutect2
- CAMSAP1 | c.408C>T p.R136= | Silent (SNP) | VAF 48/96 reads (50%) | catalogued as rs760628469; called by mutect2, varscan2
